Somatic mutation profile of tumor specimen 0DSMY1 from CCDI case PBCHTN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Gastrointestinal stromal tumor, NOS; Tissue or organ of origin: Gastric antrum; Age at diagnosis: 17.7 years (6,451 days).
Specimen 0DSMY1: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4757abce-ab83-4eb5-b3b8-6ffde06a3761.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSMYE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a2da43-4416-4d05-af30-c122e8586d9e

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, 3'UTR 2, Missense Mutation 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VGLL1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV65703631; called by muse, mutect2
- FAM187B | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, varscan2
- ZNF655 | c.1106_1107insCAACA p.K369Nfs*25 | Frame Shift Ins (INS) | VAF 92/453 reads (20%) | called by mutect2, varscan2*
- GREB1 | c.4272G>T p.L1424= | Silent (SNP) | VAF 74/431 reads (17%) | catalogued as rs772826104, COSV52190854; called by muse, mutect2, varscan2
- NBEAL2 | c.2892C>T p.H964= | Silent (SNP) | VAF 66/333 reads (20%) | called by muse, mutect2, varscan2
- ARHGEF19 | c.-23G>A | 5'UTR (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- CPNE4 | c.*84A>G | 3'UTR (SNP) | VAF 14/109 reads (13%) | catalogued as COSV70200551; called by muse, varscan2
- SEMA4G | c.*469G>A | 3'UTR (SNP) | VAF 56/262 reads (21%) | catalogued as rs986972740; called by muse, mutect2, varscan2
